Gene-level copy-number profile of tumor specimen TCGA-06-5415-01A from TCGA case TCGA-06-5415, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.8 years (22,213 days).
Specimen TCGA-06-5415-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.3258d8a2-37fe-4912-8a43-f54606932a54.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-5415-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a7544266-2ba5-429a-a149-3443a3936d37

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 91; copy number 1: 7,749; copy number 2: 42,223; copy number 3: 9,724; copy number 12: 18; copy number 42: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-5415-01A-01D-1479-01): tumor purity 0.83, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 87 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,341,669–20,622,499, 1 gene (within-gene range 0–1): MLLT3.
- chr9:20,502,265–26,118,408, 86 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 31 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,621,025–55,344,958, 13 genes, copy number 42: RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1.
- chr14:104,474,678–104,845,916, 18 genes, copy number 12 (within-gene range 2–12): TMEM179, C14orf180, BX927359.1, AL583722.2, LINC02280, MIR4710, INF2, AL583722.3, ADSS1, SIVA1, AL583722.1, AKT1, ZBTB42, AL590326.1, LINC00638, RPS26P49, RPS2P4, AL583810.2.

Autosomal genes at a single copy (total copy number 1): 5,373. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
